Somatic mutation profile of tumor specimen TCGA-64-5778-01A (aliquot TCGA-64-5778-01A-01D-1625-08) from TCGA case TCGA-64-5778, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Bronchiolo-alveolar carcinoma, non-mucinous; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 60.0 years (21,927 days).
Specimen TCGA-64-5778-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 26b2b1c8-8f78-4ef9-a90e-f5744154b8b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-64-5778-10A (Blood Derived Normal), aliquot TCGA-64-5778-10A-01D-1625-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/02f8051b-eeba-4da3-a517-b0b92ff4efac

The open-access MAF lists 506 somatic variants for this specimen: 397 protein-altering or splice-affecting, 98 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 342, Silent 98, Nonsense Mutation 23, Frame Shift Del 13, Splice Site 9, Frame Shift Ins 5, Intron 4, Splice Region 4, 5'Flank 2, RNA 2, In Frame Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL6A2 | c.186dup p.T63Hfs*41 | Frame Shift Ins (INS) | VAF 10/51 reads (20%) | catalogued as rs886041439; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.716A>G p.N239S | Missense Mutation (SNP) | VAF 9/23 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.772); catalogued as rs1057519999, COSV52661127, COSV52664176, COSV52966384; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB4 | c.2903T>C p.M968T | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.168); catalogued as rs1302208239, COSV55935880; called by muse, mutect2, varscan2
- ABCB5 | c.3488G>T p.R1163I (on ENST00000404938 / NM_001163941.2; = p.R718I on NM_178559.6) | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51710752; called by muse, mutect2, varscan2
- ABCG8 | c.551G>T p.R184L | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as CM012312, COSV55390446, COSV55393699; called by muse, mutect2, varscan2
- ABLIM2 | c.491A>T p.Q164L | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV56405072; called by muse, mutect2, varscan2
- ACO1 | c.1174T>A p.C392S | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.109); catalogued as COSV59380470; called by muse, mutect2, varscan2
- ACTR3B | c.1034C>T p.A345V | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as COSV55449592; called by muse, mutect2, varscan2
- ADAM33 | c.545G>T p.R182M | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.525); catalogued as COSV62934980; called by muse, mutect2, varscan2
- ADAMTS20 | c.1381G>T p.E461* | Nonsense Mutation (SNP) | VAF 10/31 reads (32%) | catalogued as COSV67132452, COSV67137047; called by muse, mutect2, varscan2
- ADAMTS9 | c.5188G>T p.V1730F | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.053); catalogued as COSV55782191; called by muse, mutect2, varscan2
- ADGRG4 | c.3344G>C p.R1115T | Missense Mutation (SNP) | VAF 48/87 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV54957344; called by muse, mutect2, varscan2
- ADGRL3 | c.1345A>C p.N449H (on ENST00000506720 / NM_001322402.2; = p.N381H on NM_015236.6) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72268792; called by muse, mutect2, varscan2
- AGBL2 | c.1156G>A p.D386N | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.119); catalogued as COSV54092487; called by muse, mutect2, varscan2
- AHDC1 | c.1422G>T p.M474I | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.36); PolyPhen benign (0.047); catalogued as COSV55939263; called by muse, mutect2, varscan2
- AMER2 | c.1564G>T p.E522* | Nonsense Mutation (SNP) | VAF 24/55 reads (44%) | catalogued as COSV63437872; called by muse, mutect2, varscan2
- ANK2 | c.7988C>A p.S2663Y | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52156548, COSV52163748; called by muse, mutect2, varscan2
- ANXA13 | c.719-2A>G p.X240_splice | Splice Site (SNP) | VAF 14/46 reads (30%) | catalogued as COSV51623746; called by muse, mutect2, varscan2
- AP3B2 | c.2128G>T p.G710C | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.552); catalogued as COSV99916076; called by muse, mutect2, varscan2
- APBA2 | c.133G>T p.G45C | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.365); catalogued as COSV68791771; called by muse, mutect2, varscan2
- APOB | c.9460del p.E3154Kfs*5 | Frame Shift Del (DEL) | VAF 32/116 reads (28%) | catalogued as COSV51934657; called by mutect2, pindel, varscan2
- APOB | c.5771C>A p.T1924N | Missense Mutation (SNP) | VAF 59/198 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.586); catalogued as COSV51937460; called by muse, mutect2, varscan2
- APP | c.2240G>C p.R747P | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100695759, COSV60999108; called by muse, mutect2, varscan2
- ARHGAP36 | c.202T>A p.Y68N | Missense Mutation (SNP) | VAF 53/82 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52267447; called by muse, mutect2, varscan2
- ARHGEF35 | c.605G>A p.G202E | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.02); catalogued as rs1427515927; called by mutect2, varscan2
- ARMC8 | c.852G>T p.L284F (on ENST00000469044 / NM_001363941.2; = p.L270F on NM_014154.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100627500, COSV61769072; called by muse, mutect2, varscan2
- ARPP21 | c.1875G>C p.Q625H | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.73); catalogued as COSV51798973; called by mutect2, varscan2
- ASTL | c.955G>T p.E319* | Nonsense Mutation (SNP) | VAF 15/46 reads (33%) | catalogued as COSV60904409; called by muse, mutect2, varscan2
- ASTN2 | c.1244C>A p.T415K (on ENST00000313400 / NM_001365069.1; = p.T364K on NM_014010.5) | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV100529134, COSV57747172; called by muse, mutect2, varscan2
- ATP1A4 | c.1452G>C p.K484N | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1317166473, COSV63626716; called by muse, mutect2, varscan2
- ATP2B4 | c.776G>T p.G259V | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58178535; called by muse, mutect2, varscan2
- ATRN | c.3749A>G p.N1250S | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as COSV53528378; called by muse, mutect2, varscan2
- AXDND1 | c.410A>T p.K137I | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.358); catalogued as COSV62643273; called by muse, mutect2, varscan2
- BEST3 | c.1236C>A p.S412R | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs775940932, COSV100437591; called by muse, mutect2, varscan2
- BRD2 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV66373460; called by muse, mutect2, varscan2
- C20orf85 | c.69-1G>T p.X23_splice | Splice Site (SNP) | VAF 52/147 reads (35%) | catalogued as COSV64519410; called by muse, mutect2, varscan2
- C3orf20 | c.1465G>T p.G489* | Nonsense Mutation (SNP) | VAF 38/111 reads (34%) | catalogued as COSV53785763; called by muse, mutect2, varscan2
- CACHD1 | c.745G>C p.D249H | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV51553996, COSV99261936; called by muse, mutect2, varscan2
- CACNA1B | c.1185G>T p.A395= | Splice Region (SNP) | VAF 11/13 reads (85%) | catalogued as COSV99495352; called by muse, mutect2, varscan2
- CACNA1F | c.5014C>A p.R1672S | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV59904760; called by muse, mutect2, varscan2
- CADPS | c.485C>A p.A162D | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV51882095, COSV51903923; called by muse, mutect2, varscan2
- CC2D1B | c.2494G>T p.V832L | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV52560496; called by muse, mutect2
- CCDC178 | c.274C>A p.P92T | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55775818; called by muse, mutect2, varscan2
- CCR3 | c.712A>G p.I238V | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as COSV100656336; called by muse, mutect2, varscan2
- CD5L | c.172G>T p.V58L | Missense Mutation (SNP) | VAF 61/182 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.667); catalogued as COSV63822127; called by muse, mutect2, varscan2
- CDC40 | c.1588G>T p.G530* | Nonsense Mutation (SNP) | VAF 14/59 reads (24%) | catalogued as COSV57009814; called by muse, mutect2, varscan2
- CDH10 | c.1225A>G p.R409G | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.355); catalogued as rs757220666, COSV52582709; called by muse, mutect2, varscan2
- CDH19 | c.848A>G p.N283S | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.77); PolyPhen benign (0.026); catalogued as COSV50960220; called by muse, mutect2, varscan2
- CDHR2 | c.565G>C p.G189R | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as COSV56139576; called by muse, mutect2, varscan2
- CELF1 | c.370A>G p.I124V | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60112263; called by muse, mutect2, varscan2
- CFAP43 | c.4216G>A p.E1406K | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.455); catalogued as COSV63853276; called by muse, mutect2, varscan2
- CFAP74 | c.4428T>G p.C1476W | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV60587130; called by muse, mutect2, varscan2
- CFH | c.243G>T p.Q81H | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.049); catalogued as COSV104415170, COSV62777623, COSV62777732; called by muse, mutect2, varscan2
- CHL1 | c.3262T>A p.C1088S (on ENST00000397491 / NM_001253387.1; = p.C1104S on NM_006614.4) | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.694); catalogued as COSV56594700; called by muse, mutect2, varscan2
- CHRDL1 | c.1269G>C p.M423I (on ENST00000372045; = p.M429I on NM_145234.4) | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.054); catalogued as COSV54323189, COSV54325546; called by muse, mutect2, varscan2
- CHRND | c.145G>T p.E49* | Nonsense Mutation (SNP) | VAF 22/100 reads (22%) | catalogued as COSV51318366, COSV51320011; called by muse, mutect2, varscan2
- CLDN8 | c.200A>G p.Y67C | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766571800, COSV54526039; called by muse, mutect2, varscan2
- CLTCL1 | c.527G>T p.R176L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.937); catalogued as COSV54227309, COSV99594550; called by muse, mutect2
- COL19A1 | c.2524G>T p.G842W | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100505244; called by muse, mutect2, varscan2
- COL19A1 | c.2525G>T p.G842V | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100505246; called by muse, mutect2, varscan2
- COL5A1 | c.2566G>C p.G856R | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65669528; called by mutect2, varscan2
- COL7A1 | c.6393+1G>C p.X2131_splice | Splice Site (SNP) | VAF 19/68 reads (28%) | catalogued as COSV60395896, COSV60397362; called by muse, mutect2, varscan2
- COPG2 | c.664G>C p.G222R | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.689); catalogued as COSV58405456; called by muse, mutect2, varscan2
- CPLANE1 | c.*3179A>T | Splice Region (SNP) | VAF 19/146 reads (13%) | catalogued as COSV57061411; called by muse, mutect2, varscan2
- CRB2 | c.3508T>A p.C1170S | Missense Mutation (SNP) | VAF 37/61 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63503489; called by muse, mutect2, varscan2
- CRTC2 | c.1982A>T p.E661V | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV57843189; called by muse, mutect2, varscan2
- CSF2RB | c.2091G>A p.M697I | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs138676111; called by muse, mutect2, varscan2
- CSMD3 | c.7717G>T p.E2573* (on ENST00000297405 / NM_001363185.1; = p.E2469* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 6/64 reads (9%) | catalogued as COSV99825501; called by muse, mutect2
- CSNK1D | c.270G>T p.E90D | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.647); catalogued as COSV53924768; called by muse, mutect2, varscan2
- CTNND2 | c.1535T>A p.V512D | Missense Mutation (SNP) | VAF 30/192 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.163); catalogued as COSV58892492; called by muse, mutect2, varscan2
- CYLC1 | c.1343C>A p.S448Y | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100254077; called by muse, mutect2
- DACH1 | c.2210G>T p.G737V (on ENST00000619232 / NM_001366712.1; = p.G483V on NM_004392.6) | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.164); catalogued as rs750702072, COSV57501980; called by muse, mutect2, varscan2
- DACH2 | c.838C>A p.H280N | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT tolerated (0.25); PolyPhen benign (0.25); catalogued as COSV64170392; called by muse, mutect2, varscan2
- DCN | c.1007A>T p.Y336F | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as COSV50007277; called by muse, mutect2, varscan2
- DDX50 | c.1511A>T p.E504V | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65292346; called by muse, mutect2, varscan2
- DLGAP1 | c.2614G>T p.G872W | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59807184; called by muse, mutect2, varscan2
- DMD | c.4074T>A p.A1358= | Splice Region (SNP) | VAF 19/23 reads (83%) | catalogued as COSV63758340; called by muse, mutect2, varscan2
- DNAH11 | c.9787A>G p.I3263V | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs751955484, COSV60958074; called by muse, mutect2, varscan2
- DNAH3 | c.6227C>G p.T2076R | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54525003; called by muse, mutect2, varscan2
- DNAI2 | c.31C>A p.R11S | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV56759115; called by muse, mutect2, varscan2
- DNAJC1 | c.661G>C p.D221H | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65376187; called by muse, mutect2, varscan2
- DNMT3A | c.935C>T p.S312F | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV53054926, COSV53063782; called by muse, mutect2, varscan2
- DPP10 | c.577-1G>C p.X193_splice | Splice Site (SNP) | VAF 14/42 reads (33%) | catalogued as COSV59690090, COSV59706581; called by muse, mutect2, varscan2
- DSCAML1 | c.1121C>T p.P374L (on ENST00000321322; = p.P314L on NM_020693.4) | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); catalogued as COSV58391770; called by muse, mutect2, varscan2
- DYNC1I1 | c.1254G>T p.W418C | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61461679; called by muse, mutect2, varscan2
- DZIP3 | c.1558G>T p.G520C | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV64312233; called by muse, mutect2, varscan2
- EBF1 | c.1474G>T p.G492C | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.908); catalogued as COSV58180148; called by muse, mutect2, varscan2
- EEPD1 | c.1577G>T p.G526V | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54198747; called by muse, mutect2, varscan2
- EFCAB5 | c.1585G>T p.G529C | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.917); catalogued as COSV57930839; called by muse, mutect2, varscan2
- EFS | c.1028G>T p.R343L | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.81); PolyPhen benign (0.011); catalogued as COSV53732607, COSV53733823; called by muse, mutect2, varscan2
- EHD1 | c.1348G>A p.E450K | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.039); catalogued as rs1279892217, COSV57734443; called by muse, mutect2, varscan2
- ELAPOR1 | c.1964A>G p.Y655C | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV64040524; called by mutect2, varscan2
- ENTPD1 | c.1016C>A p.P339H | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV64601916; called by muse, mutect2, varscan2
- EPHA6 | c.2299C>A p.Q767K (on ENST00000389672 / NM_001080448.3; = p.Q159K on NM_173655.4) | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV67574328; called by muse, mutect2, varscan2
- ERBB4 | c.1918G>T p.G640C | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.163); catalogued as COSV53537388; called by muse, mutect2, varscan2
- ESF1 | c.1070G>T p.W357L | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52521285; called by muse, mutect2, varscan2
- EVC2 | c.3398T>A p.M1133K | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100185108; called by muse, mutect2
- F2 | c.388C>A p.Q130K | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61315919; called by muse, mutect2, varscan2
- F2RL2 | c.1112A>T p.Y371F | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV56970820; called by muse, mutect2, varscan2
- FAM47B | c.1911C>A p.D637E | Missense Mutation (SNP) | VAF 41/63 reads (65%) | SIFT tolerated (0.34); PolyPhen benign (0.03); catalogued as COSV61454062, COSV61454257; called by muse, mutect2, varscan2
- FAT2 | c.12170C>T p.A4057V | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as rs767959528, COSV55820643; called by mutect2, varscan2
- FBN2 | c.5586G>T p.Q1862H | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as COSV52516629; called by muse, mutect2, varscan2
- FBN3 | c.6496G>T p.D2166Y | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54462192; called by muse, mutect2, varscan2
- FBXL19 | c.956G>T p.R319L | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV57942769; called by muse, mutect2, varscan2
- FCGBP | c.8009G>A p.G2670E | Missense Mutation (SNP) | VAF 46/184 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769272171; called by muse, mutect2, varscan2
- FLG | c.10316G>T p.G3439V | Missense Mutation (SNP) | VAF 130/391 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV64242527, COSV64244485; called by muse, mutect2, varscan2
- FLG2 | c.2606C>A p.S869Y | Missense Mutation (SNP) | VAF 145/226 reads (64%) | SIFT tolerated (0.31); PolyPhen benign (0.443); catalogued as COSV66169104; called by muse, mutect2, varscan2
- FOXG1 | c.1009C>A p.H337N | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.351); catalogued as COSV57397103; called by muse, mutect2, varscan2
- FYB1 | c.266G>T p.G89V | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT tolerated (0.19); PolyPhen benign (0.274); catalogued as COSV60947579; called by muse, mutect2, varscan2
- GALNT17 | c.652G>T p.V218L | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.534); catalogued as COSV100352452; called by muse, mutect2, varscan2
- GBA3 | c.263C>A p.T88K | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV72438172; called by muse, mutect2, varscan2
- GBP5 | c.951G>C p.L317F | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58592941; called by muse, mutect2, varscan2
- GDF6 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs900181760, COSV54625377, COSV54628380; called by muse, mutect2, varscan2
- GPNMB | c.1088G>A p.R363K (on ENST00000381990 / NM_001005340.2; = p.R351K on NM_002510.3) | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV51698846; called by muse, mutect2, varscan2
- GPR61 | c.784C>G p.R262G | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV100879809, COSV63983835; called by muse, mutect2, varscan2
- GRB2 | c.602A>T p.Q201L | Missense Mutation (SNP) | VAF 47/203 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV57304938; called by muse, mutect2, varscan2
- GRIN3A | c.1061G>T p.W354L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as COSV62454319; called by muse, mutect2, varscan2
- GRK5 | c.1769G>T p.S590I | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as rs1336713615, COSV64866488; called by muse, mutect2, varscan2
- GSTP1 | c.352G>T p.D118Y | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.616); catalogued as COSV101282007; called by muse, mutect2, varscan2
- GUCA1C | c.505G>T p.V169F | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.473); catalogued as COSV53753382; called by muse, mutect2, varscan2
- H2AC6 | c.352C>G p.P118A | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.065); catalogued as COSV58416328, COSV58417281; called by muse, mutect2, varscan2
- H3C10 | c.406G>T p.A136S | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.028); catalogued as rs1293034525, COSV100297491; called by muse, mutect2, varscan2
- H6PD | c.2176C>G p.H726D | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.224); catalogued as COSV66231118; called by muse, mutect2, varscan2
- HOXA3 | c.433dup p.L145Pfs*88 | Frame Shift Ins (INS) | VAF 19/64 reads (30%) | catalogued as rs753346052; called by mutect2, pindel, varscan2
- HOXB3 | c.567G>T p.K189N | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as COSV57486992; called by muse, mutect2, varscan2
- HOXC13 | c.874C>G p.R292G | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV54498859, COSV54500557; called by muse, mutect2, varscan2
- HUWE1 | c.1948G>A p.D650N | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53347507; called by muse, mutect2, varscan2
- IFI16 | c.1687G>T p.E563* (on ENST00000295809 / NM_001364867.2; = p.E507* on NM_005531.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 31/79 reads (39%) | catalogued as COSV99857061; called by muse, mutect2, varscan2
- IGF2BP3 | c.1220C>G p.T407S | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.549); catalogued as COSV51685545; called by muse, mutect2, varscan2
- IGHV3-74 | c.290C>A p.T97K | Missense Mutation (SNP) | VAF 75/183 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.106); catalogued as rs184901617; called by muse, mutect2, varscan2
- IGKV1-5 | c.167C>G p.A56G | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as rs749425801; called by muse, mutect2, varscan2
- IGSF3 | c.3255G>T p.W1085C (on ENST00000369486 / NM_001007237.3; = p.W1105C on NM_001542.4) | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59591587; called by muse, mutect2, varscan2
- IL20RB | c.808G>A p.V270I | Missense Mutation (SNP) | VAF 69/294 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.048); catalogued as rs370491517, COSV59049010; called by muse, mutect2, varscan2
- IL9R | c.432C>A p.H144Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs747804769, COSV54900094; called by muse, mutect2, varscan2
- IMPG2 | c.2537G>T p.G846V | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.834); catalogued as COSV51979089; called by muse, mutect2, varscan2
- INHBA | c.529C>G p.Q177E | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.489); catalogued as COSV54221936; called by muse, mutect2, varscan2
- IQGAP2 | c.1321G>T p.D441Y | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.168); catalogued as COSV57174303; called by muse, mutect2, varscan2
- ISOC2 | c.280G>T p.E94* | Nonsense Mutation (SNP) | VAF 8/17 reads (47%) | catalogued as COSV99321059; called by muse, mutect2, varscan2
- ISOC2 | c.279G>T p.Q93H | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV99321063; called by muse, mutect2, varscan2
- ITGA1 | c.2005G>T p.V669L | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0.112); catalogued as COSV50883313, COSV50904183; called by muse, mutect2, varscan2
- ITGAD | c.1540G>T p.G514C | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV66758281, COSV66758637; called by muse, mutect2, varscan2
- IVL | c.486C>A p.H162Q | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.74); PolyPhen benign (0.113); catalogued as COSV100908115; called by muse, varscan2
- KATNIP | c.1961A>G p.E654G | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.311); catalogued as COSV55181691; called by muse, mutect2, varscan2
- KATNIP | c.2737C>T p.R913C | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150681595; called by muse, mutect2, varscan2
- KCNA3 | c.1225del p.V409Sfs*32 | Frame Shift Del (DEL) | VAF 14/41 reads (34%) | catalogued as COSV63902578; called by mutect2, pindel, varscan2
- KDR | c.4016C>A p.T1339K | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.003); catalogued as rs1315952875, COSV55766375, COSV55769546; called by muse, mutect2, varscan2
- KDR | c.1134A>T p.K378N | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as COSV55766388; called by muse, mutect2, varscan2
- KIAA2026 | c.4390G>T p.V1464L | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV67355258; called by muse, mutect2, varscan2
- KIF1A | c.1494C>A p.N498K | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV100239898; called by muse, mutect2, varscan2
- KIF2B | c.419G>C p.C140S | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as rs1043953889, COSV52131104; called by muse, mutect2, varscan2
- KIF4A | c.2597C>A p.A866D | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65543483; called by muse, mutect2, varscan2
- KIR2DL4 | c.1045C>G p.Q349E (on ENST00000396284; = p.Q275E on NM_001080770.2) | Missense Mutation (SNP) | VAF 134/268 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.234); catalogued as rs767830266, COSV100428852; called by muse, varscan2
- KLHL9 | c.691G>T p.D231Y | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.485); catalogued as COSV100757004; called by muse, mutect2, varscan2
- KRT71 | c.956C>A p.A319D | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57290852; called by muse, mutect2, varscan2
- KRTAP13-1 | c.23G>A p.G8E | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV62663469; called by muse, mutect2, varscan2
- KRTAP19-6 | c.116A>G p.Y39C | Missense Mutation (SNP) | VAF 52/171 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.039); catalogued as COSV61844070; called by muse, mutect2, varscan2
- KRTAP9-3 | c.274C>A p.Q92K | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.25); catalogued as COSV68616458; called by muse, mutect2, varscan2
- LAMA2 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); catalogued as COSV70348393; called by muse, mutect2, varscan2
- LAMA2 | c.7117T>A p.S2373T | Missense Mutation (SNP) | VAF 41/178 reads (23%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.487); catalogued as COSV70348397; called by muse, mutect2, varscan2
- LCORL | c.530G>T p.G177V | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.188); catalogued as COSV100481573; called by muse, mutect2, varscan2
- LCT | c.4636G>T p.G1546C | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51550402; called by muse, mutect2, varscan2
- LDB3 | c.478G>T p.D160Y | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV99554776; called by muse, mutect2, varscan2
- LILRA2 | c.842C>T p.T281I | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as rs745872755, COSV52192279; called by muse, mutect2, varscan2
- LIX1 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV57207066; called by muse, mutect2, varscan2
- LRP1B | c.3190G>A p.G1064S | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.967); catalogued as COSV67199567, COSV67247877; called by muse, mutect2, varscan2
- LRP1B | c.786C>G p.I262M | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV67226486; called by muse, mutect2, varscan2
- LRP2 | c.12980A>G p.N4327S | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.355); catalogued as COSV55555758; called by muse, mutect2, varscan2
- LRRC1 | c.235G>T p.A79S | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.856); catalogued as rs368836742, COSV100906008; called by muse, mutect2, varscan2
- LRRC40 | c.1399G>T p.E467* | Nonsense Mutation (SNP) | VAF 17/38 reads (45%) | catalogued as COSV100918876, COSV63942437; called by muse, mutect2, varscan2
- LRRC7 | c.886C>A p.L296I (on ENST00000651989 / NM_001370785.2; = p.L263I on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as COSV50468019, COSV50610652; called by muse, mutect2
- LRRC73 | c.529G>T p.V177F | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.427); catalogued as COSV52499442, COSV52501184; called by muse, mutect2, varscan2
- LYST | c.3064C>A p.Q1022K | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV67707564; called by muse, mutect2, varscan2
- MACROH2A2 | c.395C>A p.P132Q | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); catalogued as COSV64712940; called by muse, mutect2, varscan2
- MAGEC1 | c.4+1G>T p.X2_splice | Splice Site (SNP) | VAF 21/42 reads (50%) | catalogued as COSV53573671; called by muse, mutect2, varscan2
- MAGEC1 | c.2909C>A p.P970H | Missense Mutation (SNP) | VAF 76/135 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53573257, COSV53573679; called by muse, mutect2, varscan2
- MAP2 | c.4253G>T p.R1418L | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV52292592; called by muse, mutect2, varscan2
- MAP3K14 | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV60923720; called by muse, mutect2, varscan2
- MAP3K4 | c.1150A>G p.K384E | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.278); catalogued as COSV62334203; called by muse, mutect2, varscan2
- MAPKAPK5 | c.868G>T p.E290* | Nonsense Mutation (SNP) | VAF 13/23 reads (57%) | catalogued as COSV73436087; called by muse, mutect2, varscan2
- MARCO | c.274C>A p.P92T | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.043); catalogued as COSV100503214, COSV59055345; called by muse, mutect2, varscan2
- MARCO | c.275C>A p.P92Q | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as COSV100503216, COSV59057883; called by muse, mutect2, varscan2
- MARS2 | c.982G>T p.G328C | Missense Mutation (SNP) | VAF 50/194 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56571408, COSV56572067; called by muse, mutect2, varscan2
- MARS2 | c.1341T>A p.Y447* | Nonsense Mutation (SNP) | VAF 29/112 reads (26%) | catalogued as COSV56571414; called by muse, mutect2, varscan2
- MATK | c.362C>T p.P121L (on ENST00000310132 / NM_139355.3; = p.P122L on NM_002378.4) | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as rs773709945, COSV59554931; called by muse, mutect2, varscan2
- MEGF6 | c.311C>A p.A104D | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.067); catalogued as COSV62993290; called by muse, mutect2, varscan2
- MMP10 | c.791C>A p.P264H | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.176); catalogued as COSV54246407; called by muse, mutect2
- MMRN1 | c.850G>T p.A284S | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.339); catalogued as COSV99306502; called by muse, mutect2, varscan2
- MSANTD1 | c.562G>T p.D188Y | Missense Mutation (SNP) | VAF 55/163 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as rs138360402, COSV101433561; called by muse, mutect2, varscan2
- MUC16 | c.33815A>T p.E11272V | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.882); catalogued as COSV67469387; called by muse, mutect2, varscan2
- MUC16 | c.23294C>T p.A7765V | Missense Mutation (SNP) | VAF 76/164 reads (46%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV67469393; called by muse, mutect2, varscan2
- MUC5B | c.14261C>T p.P4754L | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs760116197, COSV101500042; called by muse, mutect2, varscan2
- MYH7 | c.5167C>A p.L1723I | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV62519799; called by muse, mutect2, varscan2
- MYO1E | c.175G>T p.V59F | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55688287; called by muse, mutect2, varscan2
- MYOD1 | c.790C>A p.P264T | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs1416156860, COSV100000133; called by muse, mutect2, varscan2
- MYOM2 | c.1464C>T p.A488= | Splice Region (SNP) | VAF 29/198 reads (15%) | catalogued as rs376844864; called by muse, mutect2, varscan2
- NCAM2 | c.1594G>T p.V532L | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV53078339; called by muse, mutect2, varscan2
- NFAM1 | c.536T>A p.V179E | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as COSV61195318; called by muse, mutect2
- NIFK | c.571C>T p.Q191* | Nonsense Mutation (SNP) | VAF 14/45 reads (31%) | catalogued as COSV53534956; called by muse, mutect2, varscan2
- NLGN4X | c.889A>T p.T297S | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.699); catalogued as COSV52020385; called by muse, mutect2, varscan2
- NLRP3 | c.685G>A p.G229R | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60225120; called by muse, mutect2, varscan2
- NPR1 | c.2350T>C p.W784R | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64117657; called by muse, mutect2, varscan2
- NR1H3 | c.680G>T p.R227L | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as rs779302187, COSV101269721, COSV68008357; called by muse, mutect2, varscan2
- NT5DC3 | c.667G>T p.E223* | Nonsense Mutation (SNP) | VAF 22/49 reads (45%) | catalogued as COSV67321846; called by muse, mutect2, varscan2
- NUF2 | c.747G>C p.E249D | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV54844110; called by muse, mutect2, varscan2
- NUP205 | c.515G>T p.R172L | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); catalogued as COSV53658239, COSV53659887; called by muse, mutect2, varscan2
- NUP214 | c.2497G>T p.D833Y | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63910016; called by muse, mutect2, varscan2
- OAZ3 | c.501C>A p.Y167* | Nonsense Mutation (SNP) | VAF 48/238 reads (20%) | catalogued as COSV100162339, COSV58619734; called by muse, mutect2, varscan2
- OLFML2B | c.1708G>T p.V570L | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV54196754; called by muse, mutect2, varscan2
- OR10Z1 | c.874C>A p.L292I | Missense Mutation (SNP) | VAF 109/292 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV63525009; called by muse, mutect2, varscan2
- OR11G2 | c.962C>A p.P321Q | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100640030, COSV62132377; called by muse, mutect2, varscan2
- OR13D1 | c.539C>A p.S180Y | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59514058; called by muse, mutect2, varscan2
- OR13G1 | c.9C>A p.H3Q | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62944367; called by muse, mutect2, varscan2
- OR1N1 | c.731G>T p.C244F | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV59195833; called by muse, mutect2, varscan2
- OR2AK2 | c.747C>A p.S249R | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV63553611; called by muse, mutect2, varscan2
- OR2G6 | c.447G>T p.W149C | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771155581, COSV100598033; called by muse, mutect2, varscan2
- OR2T3 | c.550T>A p.C184S | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62082619; called by muse, mutect2, varscan2
- OR2W3 | c.590G>T p.G197V | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.506); catalogued as COSV64457004; called by muse, mutect2, varscan2
- OR4N2 | c.15C>A p.N5K | Missense Mutation (SNP) | VAF 39/170 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as COSV60050768, COSV60051788; called by muse, mutect2, varscan2
- OR52N4 | c.598T>A p.Y200N | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57891299; called by muse, mutect2, varscan2
- OR56A3 | c.376C>A p.R126S | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV61568506, COSV61569191; called by muse, mutect2, varscan2
- OR5D14 | c.328G>T p.V110L | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV59456573; called by muse, mutect2
- OR8H2 | c.723C>A p.C241* | Nonsense Mutation (SNP) | VAF 21/65 reads (32%) | catalogued as COSV57944926, COSV57945379; called by muse, mutect2, varscan2
- OR8J3 | c.926G>T p.C309F | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV56881510; called by muse, mutect2, varscan2
- OSBPL7 | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.425); catalogued as rs776795614, COSV50109206; called by muse, mutect2, varscan2
- OSM | c.229C>A p.R77S | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV53161433; called by muse, mutect2, varscan2
- OTUB2 | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.158); catalogued as rs968152272, COSV52573599; called by muse, mutect2, varscan2
- PAM | c.644-2A>G p.X215_splice | Splice Site (SNP) | VAF 19/53 reads (36%) | catalogued as COSV99173064; called by muse, mutect2, varscan2
- PANX1 | c.594G>T p.Q198H | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.426); catalogued as COSV57133010, COSV57134003; called by muse, mutect2, varscan2
- PAPPA2 | c.1705G>A p.V569I | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as rs766424114, COSV62779163; called by muse, mutect2, varscan2
- PCDH11X | c.2589G>T p.Q863H | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.953); catalogued as COSV53469894; called by muse, mutect2, varscan2
- PCDH11Y | c.1418C>A p.A473D (on ENST00000400457 / NM_032973.2; = p.A462D on NM_032971.3) | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.83); catalogued as COSV53081778; called by muse, mutect2, varscan2
- PCDHA5 | c.1135G>A p.G379S | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.926); catalogued as COSV100972116; called by muse, mutect2, varscan2
- PCDHB13 | c.1994G>T p.G665V | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as COSV53397058; called by muse, mutect2, varscan2
- PCDHGA12 | c.1049C>T p.T350I | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.951); catalogued as COSV52753594; called by muse, mutect2, varscan2
- PCLO | c.10687G>A p.G3563S | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.536); catalogued as rs750419462, COSV61638589, COSV99067667; called by muse, mutect2, varscan2
- PCSK5 | c.1024G>C p.G342R | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65089614, COSV65091940; called by muse, mutect2, varscan2
- PDCD4 | c.330G>T p.R110S | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54523156; called by muse, mutect2
- PDZRN3 | c.3045G>T p.M1015I | Missense Mutation (SNP) | VAF 29/274 reads (11%) | SIFT tolerated (0.73); PolyPhen benign (0.013); catalogued as rs1230897421, COSV55201836; called by muse, mutect2, varscan2
- PGLYRP3 | c.40G>T p.G14C | Missense Mutation (SNP) | VAF 49/167 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.754); catalogued as COSV51950476; called by muse, mutect2, varscan2
- PIK3C2G | c.3943C>T p.H1315Y (on ENST00000676171; = p.H1274Y on NM_004570.5) | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV104383790, COSV56811320; called by muse, mutect2, varscan2
- PKD2 | c.1697T>A p.V566E | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV52938600; called by muse, mutect2
- PLB1 | c.3310C>A p.L1104M | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV59826653; called by muse, mutect2, varscan2
- PLCE1 | c.1101G>T p.K367N | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); catalogued as COSV53352537; called by muse, mutect2, varscan2
- POGLUT2 | c.948A>T p.R316S | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1463830820, COSV65683163; called by muse, mutect2, varscan2
- POTEH | c.261C>A p.D87E | Missense Mutation (SNP) | VAF 66/370 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV100624818, COSV58883613; called by muse, varscan2
- PPP1R3F | c.1174G>A p.A392T | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs782564902, COSV50018499; called by muse, mutect2, varscan2
- PRPF40B | c.2297C>T p.S766F (on ENST00000380281; = p.S753F on NM_012272.3) | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV53302533, COSV53303495; called by muse, mutect2, varscan2
- PTPRZ1 | c.2839G>T p.A947S | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.007); catalogued as COSV66437569; called by muse, varscan2
- PXDN | c.4186A>G p.I1396V | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.038); catalogued as COSV53235672; called by muse, mutect2, varscan2
- RANBP9 | c.997C>G p.P333A | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV50580446, COSV99163621; called by muse, mutect2, varscan2
- RBM42 | c.161C>G p.P54R | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.444); catalogued as COSV52548122; called by muse, mutect2, varscan2
- REG3G | c.13A>G p.M5V | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV55449846; called by muse, mutect2, varscan2
- RGS22 | c.2099T>G p.L700R | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62662372; called by muse, mutect2, varscan2
- RHCE | c.651G>T p.W217C | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53800766; called by muse, mutect2, varscan2
- RIPPLY2 | c.320C>A p.A107D | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63746559; called by muse, varscan2
- RNASE3 | c.104C>A p.A35D | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100484183; called by muse, mutect2, varscan2
- RNF123 | c.2530G>A p.V844I | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs199836723, COSV57537892; called by muse, mutect2, varscan2
- RNF5 | c.70A>G p.T24A | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.83); PolyPhen benign (0.007); catalogued as rs753103073, COSV61247782; called by muse, mutect2, varscan2
- RPGRIP1 | c.2760A>T p.Q920H | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.444); catalogued as COSV99250492; called by muse, mutect2, varscan2
- RPL10L | c.484C>A p.R162S | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.217); catalogued as COSV53558822, COSV53559285; called by muse, mutect2, varscan2
- RTN4 | c.2530G>T p.D844Y | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV58268347; called by muse, mutect2, varscan2
- RTP5 | c.674C>A p.P225H | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.712); catalogued as rs745856756, COSV100574658; called by muse, mutect2, varscan2
- RYR1 | c.3410C>A p.P1137Q | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.661); catalogued as COSV62098833; called by muse, mutect2, varscan2
- RYR1 | c.10009C>T p.R3337W | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs200296387; called by muse, mutect2, varscan2
- RYR2 | c.1250G>C p.R417P | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV63688268, COSV63692084; called by muse, mutect2, varscan2
- RYR3 | c.1990C>A p.L664M | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.428); catalogued as COSV66791774; called by muse, mutect2, varscan2
- RYR3 | c.10942C>A p.L3648M (on ENST00000389232; = p.L3649M on NM_001036.6) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66791779, COSV66801451; called by muse, mutect2, varscan2
- SAMD9L | c.872A>G p.E291G | Missense Mutation (SNP) | VAF 56/160 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV59081987; called by muse, mutect2, varscan2
- SCAF11 | c.370T>G p.C124G | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV56977670; called by muse, mutect2, varscan2
- SCLT1 | c.956G>T p.C319F | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.429); catalogued as COSV99827606; called by muse, mutect2, varscan2
- SCNN1B | c.346G>T p.D116Y | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV56305061; called by muse, mutect2, varscan2
- SELP | c.812G>A p.G271E | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55252702; called by muse, mutect2, varscan2
- SEMA6B | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.044); catalogued as COSV56704043; called by muse, mutect2, varscan2
- SEPTIN4 | c.1024C>A p.Q342K | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.099); catalogued as COSV58728063; called by muse, mutect2, varscan2
- SEZ6L2 | c.1648G>T p.G550C (on ENST00000308713 / NM_001114099.3; = p.G480C on NM_012410.4) | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58099808; called by muse, mutect2, varscan2
- SGIP1 | c.1508C>A p.A503D | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52770104, COSV52770638, COSV99392643; called by muse, mutect2, varscan2
- SKA1 | c.247G>T p.D83Y | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV53278744; called by muse, mutect2, varscan2
- SKIV2L | c.125G>A p.S42N | Missense Mutation (SNP) | VAF 46/166 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV64811929; called by muse, mutect2, varscan2
- SLC10A2 | c.293T>C p.V98A | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); catalogued as rs770387114, COSV55359438; called by muse, mutect2, varscan2
- SLC16A3 | c.243C>A p.C81* | Nonsense Mutation (SNP) | VAF 25/81 reads (31%) | catalogued as COSV101125888, COSV101125904; called by muse, mutect2, varscan2
- SLC19A3 | c.122G>T p.G41V | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51452985; called by muse, mutect2, varscan2
- SLC2A10 | c.1465G>T p.G489C | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as CM1411099, COSV63714674, COSV63716448; called by muse, mutect2, varscan2
- SLC2A10 | c.1559G>T p.S520I | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.073); catalogued as rs573480396, COSV63714239, COSV63714682; called by muse, mutect2, varscan2
- SLC36A1 | c.420-1G>C p.X140_splice | Splice Site (SNP) | VAF 34/125 reads (27%) | catalogued as COSV54654186; called by muse, mutect2, varscan2
- SLC4A3 | c.394G>T p.A132S | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.011); catalogued as COSV56093609, COSV56094262; called by muse, mutect2, varscan2
- SLC5A2 | c.1255G>A p.D419N | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1032587663, COSV57891982; called by muse, mutect2, varscan2
- SLCO1C1 | c.691G>T p.V231F | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as rs1221692894, COSV56873256, COSV99859348; called by muse, mutect2, varscan2
- SLCO1C1 | c.1745C>A p.P582Q | Missense Mutation (SNP) | VAF 51/128 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV56873274; called by muse, mutect2, varscan2
- SLFN11 | c.670C>A p.Q224K | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT tolerated (0.92); PolyPhen benign (0.029); catalogued as COSV57699000; called by muse, mutect2, varscan2
- SLITRK2 | c.424G>T p.D142Y | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100157838, COSV59425737; called by muse, mutect2, varscan2
- SLITRK3 | c.112G>C p.E38Q | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV53848974; called by muse, mutect2, varscan2
- SMC1B | c.2221C>A p.L741I | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.967); catalogued as COSV100662977; called by muse, mutect2, varscan2
- SMC5 | c.272G>T p.C91F | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63193173; called by muse, mutect2, varscan2
- SMC5 | c.2953G>A p.E985K | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63193181; called by muse, mutect2
- SNAPC3 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.03); catalogued as COSV66460342; called by muse, mutect2, varscan2
- SNTG1 | c.541A>T p.N181Y | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.229); catalogued as COSV52446715; called by muse, mutect2
- SPACA1 | c.679G>T p.V227F | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as COSV52759897, COSV52760084; called by muse, mutect2, varscan2
- SPATA31E1 | c.2042C>T p.S681F | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.698); catalogued as COSV57792117; called by muse, mutect2, varscan2
- SPATA31E1 | c.2153G>T p.R718L | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.356); catalogued as COSV57792130; called by muse, mutect2, varscan2
- SPATA6 | c.79G>C p.D27H | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV64060363; called by muse, mutect2, varscan2
- SPP2 | c.217G>T p.V73F | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as rs750252210, COSV51445479; called by muse, mutect2, varscan2
- STAT5B | c.1669C>T p.Q557* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as COSV53182923; called by muse, mutect2
- STIL | c.1976C>T p.S659L | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as COSV54550649; called by muse, mutect2
- STK24 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64823005; called by muse, mutect2, varscan2
- STK38 | c.415G>T p.D139Y | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57709031; called by muse, mutect2, varscan2
- STRN | c.1143C>A p.S381R | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV55748339; called by muse, mutect2, varscan2
- SV2A | c.1589T>C p.L530P | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.905); catalogued as COSV64964937; called by muse, mutect2, varscan2
- SZT2 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs150074610; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TAAR2 | c.679G>T p.G227W (on ENST00000367931 / NM_001033080.1; = p.G182W on NM_014626.3) | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV51578960, COSV99255542; called by muse, mutect2, varscan2
- TAB2 | c.959G>T p.G320V | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV53852817; called by muse, mutect2, varscan2
- TAF1L | c.5029A>G p.T1677A | Missense Mutation (SNP) | VAF 65/199 reads (33%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); catalogued as COSV54262609; called by muse, mutect2, varscan2
- TAF1L | c.4486T>A p.C1496S | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.312); catalogued as COSV54262616; called by muse, mutect2, varscan2
- TAS2R1 | c.676G>T p.A226S | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.872); catalogued as COSV101225699; called by muse, mutect2, varscan2
- TBC1D32 | c.265G>T p.G89C | Missense Mutation (SNP) | VAF 37/173 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51544563; called by muse, mutect2, varscan2
- TBX22 | c.320A>G p.D107G | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as rs377085198, COSV64786178; called by muse, mutect2, varscan2
- TBXT | c.1028G>T p.S343I | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.056); catalogued as COSV51618281; called by muse, mutect2, varscan2
- TCF4 | c.1717G>T p.E573* | Nonsense Mutation (SNP) | VAF 43/86 reads (50%) | catalogued as rs1555710689, COSV61890504, COSV61895378, COSV61897744; called by muse, mutect2, varscan2
- TCP11 | c.709C>A p.Q237K (on ENST00000512012; = p.Q175K on NM_018679.5) | Missense Mutation (SNP) | VAF 128/443 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.622); catalogued as COSV55134177; called by muse, mutect2, varscan2
- TERB2 | c.327C>A p.D109E | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.92); PolyPhen benign (0.257); catalogued as COSV100546511; called by muse, mutect2, varscan2
- TEX35 | c.387G>T p.M129I | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV99274039; called by muse, mutect2, varscan2
- TGFB2 | c.968A>G p.Y323C | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65109469; called by muse, mutect2, varscan2
- THEM5 | c.205C>A p.L69M | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.264); catalogued as COSV64312934; called by muse, mutect2, varscan2
- THSD7A | c.785C>A p.T262N | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.028); catalogued as COSV70261806, COSV70265508; called by muse, mutect2, varscan2
- TLE3 | c.509G>T p.G170V | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.072); catalogued as COSV58169841; called by muse, mutect2, varscan2
- TMCO4 | c.404G>A p.R135K | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV53873131; called by muse, mutect2, varscan2
- TMPRSS2 | c.55G>T p.G19* | Nonsense Mutation (SNP) | VAF 9/40 reads (23%) | catalogued as COSV59823689; called by muse, mutect2, varscan2
- TNFSF4 | c.40G>T p.A14S | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.039); catalogued as COSV56056642; called by muse, mutect2, varscan2
- TPSD1 | c.93G>T p.Q31H | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.797); catalogued as COSV52976089; called by muse, varscan2
- TRAK1 | c.401A>T p.Q134L (on ENST00000327628 / NM_001349247.2; = p.Q76L on NM_014965.5) | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); catalogued as COSV58259158; called by muse, mutect2, varscan2
- TRHDE | c.2992G>C p.E998Q | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53834809, COSV53846369; called by muse, mutect2, varscan2
- TRIL | c.1246G>T p.D416Y | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.094); catalogued as COSV59867074, COSV59867239; called by muse, mutect2, varscan2
- TRIM25 | c.1613C>T p.P538L | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV57544336; called by muse, mutect2, varscan2
- TRIM33 | c.1387C>T p.P463S | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.035); catalogued as COSV61822892; called by muse, mutect2, varscan2
- TRIO | c.6075G>C p.W2025C | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60084778; called by muse, mutect2, varscan2
- TRPM6 | c.17_18insA p.E8Gfs*11 | Frame Shift Ins (INS) | VAF 17/120 reads (14%) | catalogued as COSV100665428; called by mutect2, pindel, varscan2
- TSHZ3 | c.301G>T p.E101* | Nonsense Mutation (SNP) | VAF 161/210 reads (77%) | catalogued as COSV53672746, COSV53680425; called by muse, mutect2, varscan2
- TTC3 | c.1555G>T p.G519C | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.988); catalogued as rs757988733, COSV61290819; called by muse, mutect2, varscan2
- TTN | c.59878G>A p.D19960N (on ENST00000591111; = p.D12536N on NM_003319.4) | Missense Mutation (SNP) | VAF 18/183 reads (10%) | PolyPhen probably damaging (0.998); catalogued as COSV60097908; called by muse, mutect2
- TUBB2B | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.292); catalogued as rs974931581, COSV99455272; called by muse, mutect2, varscan2
- TUBB4A | c.577G>C p.V193L | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.041); catalogued as COSV51156026; called by muse, mutect2, varscan2
- UBN2 | c.1289C>A p.T430N | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV56031011; called by muse, mutect2, varscan2
- UGT1A3 | c.136G>C p.E46Q | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.474); catalogued as COSV59389592; called by muse, mutect2, varscan2
- UMODL1 | c.1963C>T p.H655Y (on ENST00000408910 / NM_001004416.2; = p.H783Y on NM_173568.3) | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV61160426; called by muse, mutect2, varscan2
- UNC45A | c.1246C>T p.Q416* | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | catalogued as COSV67816461; called by muse, mutect2
- UPF3B | c.452T>G p.V151G | Missense Mutation (SNP) | VAF 43/68 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.277); catalogued as COSV52230208; called by muse, mutect2, varscan2
- USH2A | c.12532C>G p.P4178A | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56376915, COSV56413187; called by muse, mutect2, varscan2
- UXS1 | c.301G>T p.G101C | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99307906; called by muse, mutect2, varscan2
- VAV2 | c.2524G>T p.V842L (on ENST00000371850 / NM_001134398.2; = p.V803L on NM_003371.4) | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.329); catalogued as rs145738821, COSV64082228; called by muse, mutect2, varscan2
- VSTM1 | c.148C>A p.Q50K | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.06); catalogued as COSV58075081; called by muse, mutect2, varscan2
- VSTM4 | c.784G>T p.A262S | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV60526762; called by muse, mutect2, varscan2
- WASF1 | c.528G>T p.K176N | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as COSV55619808, COSV55621626; called by muse, mutect2, varscan2
- WDR90 | c.4234A>T p.T1412S | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.382); catalogued as COSV53470557; called by muse, mutect2, varscan2
- WNT8A | c.809C>T p.T270I | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100843016; called by muse, mutect2, varscan2
- XDH | c.733C>A p.L245M | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV65149044; called by muse, mutect2, varscan2
- YBX1 | c.392T>C p.V131A | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as COSV58438435; called by muse, mutect2, varscan2
- YBX1 | c.959A>T p.Q320L | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as rs1316864098, COSV58438446; called by muse, mutect2, varscan2
- ZFHX4 | c.4988C>A p.T1663N | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV50871535; called by muse, mutect2, varscan2
- ZFPM2 | c.1744C>G p.P582A | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.76); catalogued as rs762467813, COSV65872799; called by muse, mutect2, varscan2
- ZFY | c.1898A>C p.H633P | Missense Mutation (SNP) | VAF 26/37 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99324167; called by muse, mutect2, varscan2
- ZIM3 | c.1271G>T p.C424F | Missense Mutation (SNP) | VAF 19/230 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54143236; called by muse, mutect2
- ZMYND8 | c.3275G>T p.S1092I (on ENST00000311275 / NM_001363741.2; = p.S1066I on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.176); catalogued as COSV53685891, COSV53688515; called by muse, mutect2, varscan2
- ZNF154 | c.1223C>A p.T408N | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); catalogued as rs1222248309, COSV101377445; called by muse, mutect2, varscan2
- ZNF2 | c.1076G>T p.C359F (on ENST00000611147 / NM_001291605.2; = p.C346F on NM_021088.4) | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54637148; called by muse, mutect2, varscan2
- ZNF211 | c.743A>T p.Q248L (on ENST00000347302 / NM_198855.4; = p.Q261L on NM_006385.5) | Missense Mutation (SNP) | VAF 71/123 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as COSV53742429; called by muse, mutect2, varscan2
- ZNF25 | c.142+1G>T p.X48_splice | Splice Site (SNP) | VAF 27/100 reads (27%) | catalogued as COSV56922466; called by muse, mutect2, varscan2
- ZNF345 | c.56A>G p.E19G | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV100080166, COSV100080242; called by muse, mutect2, varscan2
- ZNF417 | c.1064G>T p.G355V | Missense Mutation (SNP) | VAF 93/197 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.969); catalogued as COSV56308535; called by muse, mutect2, varscan2
- ZNF485 | c.1314G>T p.M438I | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100700163; called by muse, mutect2, varscan2
- ZNF536 | c.2360C>A p.A787D | Missense Mutation (SNP) | VAF 42/297 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV62825258, COSV62830624; called by muse, mutect2, varscan2
- ZNF559-ZNF177 | c.887A>T p.Q296L | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV58673614; called by muse, mutect2, varscan2
- ZNF568 | c.901A>C p.T301P | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61741685; called by muse, mutect2, varscan2
- ZNF569 | c.994G>T p.G332C | Missense Mutation (SNP) | VAF 93/255 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57595784; called by muse, mutect2, varscan2
- ZNF638 | c.2962G>T p.A988S | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.629); catalogued as COSV52488146; called by muse, mutect2, varscan2
- ZNF74 | c.1741G>T p.G581W | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as rs1257886519, COSV62621328; called by muse, mutect2, varscan2
- ZNF761 | c.944G>A p.R315K | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT tolerated (0.93); PolyPhen benign (0.017); catalogued as COSV61888497; called by muse, mutect2, varscan2
- ZSCAN20 | c.236G>T p.W79L | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100792492; called by muse, mutect2, varscan2
- ZSCAN20 | c.237G>T p.W79C | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100792493; called by mutect2, varscan2
- ARPP21 | c.2215del p.Q739Sfs*41 | Frame Shift Del (DEL) | VAF 10/45 reads (22%) | called by mutect2, pindel*, varscan2
- ASB6 | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.234); called by muse, mutect2
- CELSR3 | c.6370+1del p.X2124_splice | Splice Site (DEL) | VAF 16/55 reads (29%) | called by mutect2, pindel, varscan2
- CTTNBP2 | c.2811del p.E939Sfs*27 | Frame Shift Del (DEL) | VAF 22/89 reads (25%) | called by mutect2, pindel, varscan2
- FLG | c.5545dup p.Q1849Pfs*5 | Frame Shift Ins (INS) | VAF 161/533 reads (30%) | called by mutect2, pindel, varscan2
- IGKV2-24 | c.325G>T p.G109W | Missense Mutation (SNP) | VAF 47/154 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MRC1 | c.1084T>G p.C362G | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PKD1L1 | c.6226del p.A2076Qfs*25 | Frame Shift Del (DEL) | VAF 3/25 reads (12%) | called by mutect2, pindel
- RFESD | c.200del p.G67Efs*3 | Frame Shift Del (DEL) | VAF 24/69 reads (35%) | called by mutect2, pindel, varscan2
- SLIT2 | c.2368_2369delinsT p.T791Rfs*10 | Frame Shift Del (DEL) | VAF 16/57 reads (28%) | called by pindel, varscan2*
- SPAG7 | c.139del p.E47Sfs*27 | Frame Shift Del (DEL) | VAF 18/68 reads (26%) | called by mutect2, pindel, varscan2
- STYXL2 | c.3111dup p.E1038Rfs*44 | Frame Shift Ins (INS) | VAF 18/62 reads (29%) | called by mutect2, pindel, varscan2
- TBXAS1 | c.1532_1534del p.P511del | In Frame Del (DEL) | VAF 6/38 reads (16%) | called by mutect2, pindel, varscan2
- TRAV4 | c.315C>A p.C105* | Nonsense Mutation (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2, varscan2
- TSPEAR | c.1381del p.A461Qfs*108 | Frame Shift Del (DEL) | VAF 40/159 reads (25%) | called by mutect2, pindel, varscan2
- USP33 | c.127del p.D43Ifs*6 | Frame Shift Del (DEL) | VAF 7/34 reads (21%) | called by mutect2, pindel*, varscan2
- ZNF226 | c.405del p.T136Qfs*14 | Frame Shift Del (DEL) | VAF 22/51 reads (43%) | called by mutect2, pindel, varscan2
- ZNF263 | c.260_261del p.E87Afs*77 | Frame Shift Del (DEL) | VAF 19/108 reads (18%) | called by pindel, varscan2
- ZNF804A | c.123_124del p.K42Gfs*18 | Frame Shift Del (DEL) | VAF 20/51 reads (39%) | called by pindel, varscan2
- ADA | c.1041C>A p.L347= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as COSV100596078; called by muse, mutect2, varscan2
- ADAM15 | c.1752G>A p.Q584= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV55127265, COSV55129509; called by muse, mutect2, varscan2
- ADAMTSL2 | c.495C>A p.A165= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as COSV63204422; called by muse, mutect2, varscan2
- ADRA2C | c.1305C>A p.V435= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV57467319; called by muse, mutect2
- AJAP1 | c.882A>T p.I294= | Silent (SNP) | VAF 18/103 reads (17%) | catalogued as COSV65451048; called by muse, mutect2, varscan2
- APOB | c.1672C>A p.R558= | Silent (SNP) | VAF 45/132 reads (34%) | catalogued as COSV51937469; called by muse, mutect2, varscan2
- ARHGAP17 | c.246G>T p.S82= | Silent (SNP) | VAF 64/234 reads (27%) | catalogued as COSV51507876; called by muse, mutect2, varscan2
- B4GALNT1 | c.462T>A p.V154= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV57543017; called by muse, mutect2, varscan2
- BBX | c.2790G>T p.P930= (on ENST00000325805 / NM_001142568.3; = p.P900= on NM_020235.7) | Silent (SNP) | VAF 37/130 reads (28%) | catalogued as COSV57885400; called by muse, mutect2, varscan2
- BMP10 | c.966C>T p.Y322= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV54895419; called by muse, mutect2, varscan2
- BMP7 | c.603C>T p.H201= | Silent (SNP) | VAF 40/143 reads (28%) | catalogued as COSV67780947; called by muse, mutect2
- BORCS6 | c.723C>T p.P241= | Silent (SNP) | VAF 9/12 reads (75%) | catalogued as COSV101197980; called by muse, mutect2, varscan2
- BST1 | c.816G>C p.V272= | Silent (SNP) | VAF 19/89 reads (21%) | catalogued as COSV53946975; called by muse, mutect2, varscan2
- C6orf118 | c.570C>T p.A190= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as rs756059342, COSV57813134; called by muse, mutect2, varscan2
- CDH10 | c.2296C>A p.R766= | Silent (SNP) | VAF 155/260 reads (60%) | catalogued as COSV100050202, COSV52579639, COSV52582699; called by muse, mutect2, varscan2
- CELSR3 | c.2307A>T p.A769= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as COSV50867560; called by muse, mutect2, varscan2
- CLCN1 | c.1440C>T p.P480= | Silent (SNP) | VAF 70/232 reads (30%) | catalogued as COSV58370340; called by muse, mutect2, varscan2
- COL21A1 | c.1431G>A p.K477= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs748486814, COSV55164809; called by muse, mutect2
- COL24A1 | c.1041C>T p.F347= | Silent (SNP) | VAF 17/88 reads (19%) | catalogued as COSV65307217; called by muse, mutect2, varscan2
- COLQ | c.211C>A p.R71= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as COSV67524920, COSV67526151; called by muse, mutect2, varscan2
- DTNB | c.972A>G p.P324= | Silent (SNP) | VAF 28/114 reads (25%) | catalogued as rs1406347846, COSV56477689; called by muse, mutect2, varscan2
- ENGASE | c.1206G>T p.T402= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as rs374313218, COSV100285661; called by muse, mutect2, varscan2
- EPHX4 | c.558G>T p.V186= | Silent (SNP) | VAF 38/92 reads (41%) | catalogued as COSV64889542; called by muse, mutect2, varscan2
- FBXL7 | c.708C>A p.L236= | Silent (SNP) | VAF 24/126 reads (19%) | catalogued as COSV61644402, COSV61646809; called by muse, mutect2, varscan2
- FBXW4 | c.1263C>T p.C421= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as rs148535514; called by muse, mutect2, varscan2
- FGFRL1 | c.1326T>A p.P442= | Silent (SNP) | VAF 3/15 reads (20%) | called by muse, mutect2
- FOXG1 | c.579C>G p.A193= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV57397097; called by muse, mutect2, varscan2
- GABRP | c.471T>A p.T157= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as rs1432459440, COSV54663138; called by muse, mutect2, varscan2
- GALNT17 | c.651G>T p.V217= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV100352451, COSV61190173; called by muse, mutect2, varscan2
- GART | c.2025C>T p.V675= | Silent (SNP) | VAF 29/117 reads (25%) | catalogued as COSV67818740; called by muse, mutect2, varscan2
- GBA3 | c.1371C>A p.A457= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV72438173; called by muse, mutect2, varscan2
- GNAS | c.1719C>T p.D573= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs753322339, COSV58336193; called by muse, mutect2, varscan2
- GNAZ | c.69G>T p.L23= | Silent (SNP) | VAF 29/51 reads (57%) | catalogued as rs372925670; called by muse, mutect2, varscan2
- GPR12 | c.774G>T p.G258= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as COSV67344382; called by muse, mutect2, varscan2
- GPR149 | c.45G>T p.L15= | Silent (SNP) | VAF 26/90 reads (29%) | catalogued as COSV67667610; called by muse, mutect2, varscan2
- GRXCR1 | c.786A>T p.R262= | Silent (SNP) | VAF 46/153 reads (30%) | catalogued as COSV101295623; called by muse, mutect2, varscan2
- HAP1 | c.522C>A p.V174= | Silent (SNP) | VAF 20/84 reads (24%) | catalogued as COSV57878631; called by muse, mutect2, varscan2
- HAUS5 | c.1035G>T p.G345= | Silent (SNP) | VAF 34/80 reads (43%) | catalogued as COSV52548120; called by muse, mutect2, varscan2
- HDAC9 | c.1194T>C p.H398= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV67774289; called by muse, mutect2, varscan2
- HEATR1 | c.4548G>A p.L1516= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV63981384; called by muse, mutect2, varscan2
- HUWE1 | c.2034G>T p.T678= | Silent (SNP) | VAF 14/21 reads (67%) | catalogued as COSV53333476; called by muse, mutect2, varscan2
- IFI16 | c.1686T>C p.T562= (on ENST00000295809 / NM_001364867.2; = p.T506= on NM_005531.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 30/76 reads (39%) | catalogued as COSV99857054; called by muse, mutect2, varscan2
- IL20RA | c.729A>G p.Q243= | Silent (SNP) | VAF 26/107 reads (24%) | catalogued as rs761820632, COSV57358539; called by muse, mutect2, varscan2
- IL22RA1 | c.264C>T p.L88= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV54628889; called by muse, mutect2, varscan2
- JAK1 | c.1344C>T p.Y448= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs570451668, COSV61088263; called by muse, mutect2, varscan2
- KCNJ12 | c.1065C>A p.P355= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV59167255; called by muse, mutect2, varscan2
- KLHL6 | c.273C>A p.A91= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as COSV100384559; called by muse, mutect2
- LAMB1 | c.3276C>T p.F1092= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs946517228, COSV55965171; called by muse, mutect2
- LRRC8A | c.1236G>C p.T412= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV52183715, COSV52186114; called by muse, mutect2, varscan2
- MACF1 | c.16335A>G p.Q5445= (on ENST00000372915; = p.Q3378= on NM_012090.5) | Silent (SNP) | VAF 30/97 reads (31%) | catalogued as rs1376440509, COSV57123795; called by muse, mutect2, varscan2
- MAP4K1 | c.735T>A p.A245= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV67710620; called by muse, mutect2, varscan2
- MRGPRX1 | c.345C>T p.A115= | Silent (SNP) | VAF 15/114 reads (13%) | catalogued as rs766378365, COSV57107000, COSV57110417; called by muse, varscan2
- MUSK | c.2397C>A p.G799= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV51887560; called by muse, mutect2, varscan2
- MYO16 | c.30C>A p.S10= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as COSV51797163; called by muse, mutect2, varscan2
- NNT | c.2391G>T p.V797= | Silent (SNP) | VAF 29/183 reads (16%) | catalogued as COSV52925422; called by muse, mutect2, varscan2
- NUP205 | c.5955A>G p.L1985= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as COSV53659902; called by muse, mutect2, varscan2
- OR10A4 | c.612T>G p.T204= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as COSV65842080; called by muse, mutect2, varscan2
- OR11H6 | c.795G>C p.V265= | Silent (SNP) | VAF 32/79 reads (41%) | catalogued as COSV59644320; called by muse, mutect2, varscan2
- OR4C46 | c.903T>C p.S301= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as COSV60219691; called by muse, mutect2, varscan2
- OR4Q3 | c.378C>A p.V126= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as COSV59178811, COSV59181083; called by muse, mutect2, varscan2
- OR52N2 | c.366G>T p.L122= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV57677024; called by muse, mutect2
- OR5T3 | c.429G>A p.L143= | Silent (SNP) | VAF 23/161 reads (14%) | catalogued as rs1366624298, COSV57380923; called by muse, mutect2, varscan2
- OTUD3 | c.300G>T p.V100= | Silent (SNP) | VAF 38/119 reads (32%) | catalogued as COSV64295877; called by muse, mutect2, varscan2
- P2RY1 | c.1074C>T p.T358= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as COSV59309536; called by muse, mutect2, varscan2
- PAK6 | c.1146A>T p.T382= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV53045895; called by muse, mutect2, varscan2
- PCDHB12 | c.2088A>G p.S696= | Silent (SNP) | VAF 34/284 reads (12%) | catalogued as rs528485275, COSV53401082; called by muse, mutect2
- PCDHGA12 | c.2721A>G p.A907= | Silent (SNP) | VAF 17/88 reads (19%) | catalogued as COSV52753612; called by muse, mutect2, varscan2
- PCDHGA3 | c.159G>A p.G53= | Silent (SNP) | VAF 44/173 reads (25%) | catalogued as COSV53958010; called by muse, mutect2, varscan2
- PGBD2 | c.468C>T p.F156= | Silent (SNP) | VAF 10/112 reads (9%) | catalogued as COSV61400283; called by muse, mutect2
- PGK2 | c.627G>T p.L209= | Silent (SNP) | VAF 36/132 reads (27%) | catalogued as COSV59163690, COSV59164057; called by muse, mutect2, varscan2
- PIP4K2A | c.354G>A p.R118= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as COSV60541092; called by muse, mutect2, varscan2
- PRSS58 | c.135G>A p.L45= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV101616084, COSV73488534; called by muse, mutect2, varscan2
- PTPRN | c.1995C>A p.A665= | Silent (SNP) | VAF 27/85 reads (32%) | catalogued as COSV55348528; called by muse, mutect2, varscan2
- PTPRZ1 | c.2934C>G p.T978= | Silent (SNP) | VAF 50/150 reads (33%) | catalogued as rs377203515, COSV101099983, COSV66437579, COSV66445086; called by muse, varscan2
- RFLNB | c.177G>C p.A59= | Silent (SNP) | VAF 26/60 reads (43%) | catalogued as rs782715487, COSV100225014; called by muse, mutect2, varscan2
- RHAG | c.1026C>A p.G342= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as rs754848946, COSV57704621; called by muse, mutect2, varscan2
- RHOD | c.204C>T p.H68= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV58211453; called by muse, mutect2, varscan2
- RTP5 | c.675T>A p.P225= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as rs1171572483, COSV100574659; called by muse, mutect2, varscan2
- RYR1 | c.5886G>T p.A1962= | Silent (SNP) | VAF 26/70 reads (37%) | catalogued as COSV62098838; called by muse, mutect2, varscan2
- SPAG6 | c.1062T>A p.A354= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV57620874; called by muse, mutect2, varscan2
- SPEG | c.5280A>T p.T1760= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as COSV56670155; called by muse, mutect2, varscan2
- SPEG | c.8550G>A p.R2850= | Silent (SNP) | VAF 34/114 reads (30%) | catalogued as COSV56670164; called by muse, mutect2, varscan2
- SV2A | c.555G>A p.V185= | Silent (SNP) | VAF 22/100 reads (22%) | catalogued as COSV64964940; called by muse, mutect2, varscan2
- TAAR2 | c.678G>A p.V226= (on ENST00000367931 / NM_001033080.1; = p.V181= on NM_014626.3) | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV51579826; called by muse, varscan2
- TBX4 | c.1602A>T p.S534= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as COSV53607655; called by muse, mutect2, varscan2
- TGFBI | c.1341G>A p.K447= | Silent (SNP) | VAF 8/184 reads (4%) | catalogued as COSV59351583; called by muse, mutect2
- TKTL2 | c.318C>T p.S106= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs376513845; called by muse, mutect2, varscan2
- TMPRSS11E | c.648C>T p.R216= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as COSV59519373; called by muse, mutect2, varscan2
- TRAF6 | c.1008C>T p.T336= | Silent (SNP) | VAF 25/143 reads (17%) | catalogued as rs201926351, COSV61922615; called by muse, mutect2, varscan2
- TRPC4 | c.1998C>T p.L666= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV58998880, COSV59001793; called by muse, mutect2, varscan2
- TRPM4 | c.2031A>C p.T677= | Silent (SNP) | VAF 136/257 reads (53%) | catalogued as COSV53263378; called by muse, mutect2, varscan2
- TTK | c.2343C>G p.S781= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV57884083; called by muse, mutect2, varscan2
- TUBGCP5 | c.2265G>T p.V755= | Silent (SNP) | VAF 7/47 reads (15%) | called by muse, mutect2, varscan2
- UXS1 | c.300G>T p.V100= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV99307914; called by muse, mutect2, varscan2
- VSTM2A | c.324C>A p.I108= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV56493839, COSV56494427; called by muse, mutect2
- ZFP14 | c.1404C>T p.T468= | Silent (SNP) | VAF 54/121 reads (45%) | catalogued as COSV54202118; called by muse, mutect2, varscan2
- ZNF770 | c.1713C>T p.V571= | Silent (SNP) | VAF 25/167 reads (15%) | catalogued as rs1416688129, COSV62544348; called by muse, mutect2, varscan2
- ZNF836 | c.1437C>T p.F479= | Silent (SNP) | VAF 55/112 reads (49%) | catalogued as COSV59083465; called by muse, mutect2, varscan2
- AL136439.1 | chr13:27665937 G>T | 3'Flank (SNP) | VAF 14/45 reads (31%) | catalogued as COSV68800289; called by muse, mutect2, varscan2
- C12orf77 | n.601G>A | RNA (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2
- CX3CR1 | chr3:39281683 G>T | 5'Flank (SNP) | VAF 6/22 reads (27%) | catalogued as COSV100843130; called by muse, mutect2
- ERCC6 | c.1397+8019G>T | Intron (SNP) | VAF 30/86 reads (35%) | catalogued as COSV63390558; called by muse, mutect2, varscan2
- KIF1B | c.2115+6691C>A | Intron (SNP) | VAF 6/38 reads (16%) | catalogued as COSV99822528, COSV99824460; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85476G>T | Intron (SNP) | VAF 5/10 reads (50%) | called by muse, mutect2, varscan2
- MIR646 | n.55G>C | RNA (SNP) | VAF 8/19 reads (42%) | called by muse, mutect2, varscan2
- RNU7-174P | chr8:80559566 G>T | 5'Flank (SNP) | VAF 11/31 reads (35%) | called by muse, mutect2, varscan2
- TCF12 | c.1189-834G>T | Intron (SNP) | VAF 18/45 reads (40%) | catalogued as rs765920481, COSV51019352, COSV99976380; called by muse, mutect2, varscan2
- Unknown | chr21:16071229 A>G | IGR (SNP) | VAF 32/103 reads (31%) | catalogued as rs1191159201; called by muse, mutect2, varscan2
- ZNF99 | c.*648G>T | 3'UTR (SNP) | VAF 36/112 reads (32%) | called by muse, varscan2
